Surgical pathology report (de-identified scan), TCGA case TCGA-73-4662, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-73-4662-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 4R LYMPH NODE
B. 4L LYMPH NODE
C. LEFT UPPER LOBE WEDGE
D. LEFT UPPER LOBE WEDGE
E. LEFT UPPER LOBE

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Left upper lung tumor

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA, FSB Lymph nodes, 4R, and 4L, biopsies: Negative for carcinoma.

By Dr. [REDACTED], called to [REDACTED] at [REDACTED] m.

FSC&TPD: Lung, left upper lobe, wedge biopsy: Positive for adenocarcinoma. By [REDACTED]
[REDACTED], called to [REDACTED] at [REDACTED] M.

FSE: Lung, left upper lobe, lobectomy: Bronchial margin is negative for malignancy. [REDACTED]
[REDACTED], called to [REDACTED]

GROSS DESCRIPTION:

A. 4R LYMPH NODE

Received for frozen section is a tan-pink lymph node (.8 x .6 x .4 cm). The specimen is submitted in toto for frozen section in FSA.

B. 4L LYMPH NODE

Received for frozen section is a tan-pink lymph node (.6 x .5 x .4 cm). The specimen is submitted entirely for frozen section in FSB.

[REDACTED]

[page 2 of 3]
[REDACTED]

C. LEFT UPPER LOBE WEDGE

Received for frozen section is a 7.5 x 3.4 x 2.5 tan-purple wedge resection with stapled margin. The pleural surface is tan-pink, smooth and remarkable for a palpable nodule. The pleural surface is inked black and the specimen is serially sectioned to reveal a tan-gray, firm, well-circumscribed nodule 1.5 x 1.0 x 0.6 cm, 0.5 cm from the stapled margin. A portion of the specimen is submitted for tissue procurement. The remaining lung parenchyma is grossly unremarkable. A portion of the specimen is submitted for tissue procurement. A portion of the lesion is submitted for frozen section in cassette FSA1.

C2-C4: the remainder of the lesion

C5-C6: grossly unremarkable lung parenchyma
[REDACTED]

D. LEFT UPPER LOBE WEDGE

Received in formalin and labeled [REDACTED] "left upper lobe wedge" is a 17 gram wedge of lung tissue measuring 6.2 x 4.4 x 1.3 cm. The stapled surgical margin is 9 cm in length. The pleural surface is smooth. It is inked blue and the specimen is serially sectioned. The parenchyma has a pink-tan periphery and a hemorrhagic central region. No masses or lesions are identified. Representative sections are submitted in blocks D1-D3.

E. LEFT UPPER LOBE

Received fresh for tissue procurement and frozen section and labeled [REDACTED] "left upper lobe" is a 110 gram lobectomy specimen measuring 10.4 x 7.8 x 3.5 cm. The stapled surgical margin is 13 cm in length. The pleural surface is smooth. A shaved section is taken of the bronchial margin and the bronchi are open. The bronchi are smooth and have a tan coloration. The specimen is serially sectioned and there is a well formed blood clot measuring 1.2 cm in greatest dimension which is located 0.2 cm from the stapled surgical margin. No distinct mass or lesion is identified. Multiple bronchial lymph nodes are found. Representative sections are submitted as follows:

FSE1: frozen section of bronchial margin

E2: hematoma

E3-E4: normal appearing parenchyma

E5-E6: anthracotic lymph nodes

Normal appearing lung parenchyma submitted for tissue procurement.
[REDACTED]

DIAGNOSIS:

A. LYMPH NODE, 4R, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR CARCINOMA (0/1).

B. LYMPH NODE, 4L, BIOPSY:

- ONE LYMPH NODE NEGATIVE FOR CARCINOMA (0/1)

C. LEFT LUNG, UPPER LOBE, WEDGE BIOPSY:

[REDACTED]

[page 3 of 3]
[REDACTED]

- INVASIVE, MODERATELY DIFFERENTIATED ADENOCARCINOMA, MIXED TYPES (ACINAR AND BRONCHIOLOALVEOLAR).

- TUMOR IS 2.0 CM IN MAXIMUM DIMENSION (MEASURED HISTOLOGICALLY)

- SEE SYNOPTIC TEMPLATE

D. LEFT LUNG, UPPER LOBE, WEDGE BIOPSY:

- NO CARCINOMA IDENTIFIED.
- MILD EMPHYSEMATOUS CHANGES.

E. LEFT LUNG, UPPER LOBE, LOBECTOMY:

- NO RESIDUAL CARCINOMA IDENTIFIED.
- BRONCHIAL MARGIN IS FREE OF TUMOR.
- NINE LYMPH NODES NEGATIVE FOR CARCINOMA (0/9).

SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: C: LEFT UPPER LOBE WEDGE

Surgical Procedure: Lobectomy

Laterality: Left

Tumor Site: Upper lobe

Tumor Location: Peripheral

Tumor Size: Greatest diameter: 2cm

Additional dimensions: 1.5cm x 1cm

WHO CLASSIFICATION

Adenocarcinoma

Mixed subtypes 8255/3

Histologic Grade: G2: Moderately differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Visceral Pleural Involvement: Absent

Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Negative 0 / 9

N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 1

N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 1

Additional Pathologic Findings: None identified

Pathological Staging (pTNM): pT 1 N 0 M X

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file cf4f0af5-b954-4358-bbc2-3554740789fa (TCGA-73-4662.5DD8C28F-E814-4A29-A3CD-B3524FA41941.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).